Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13W, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13W-01A (Primary Tumor).

[page 1 of 4]
Diagnostic Discrepancy		☒

Clinical Diagnosis & History:

Left thyroid nodule suspicious for follicular neoplasm on FNA.

Specimens Submitted:

- 1: SP: Para tracheal lymph node
- 2: SP: peri thyroidal lymph node
- 3: SP: Thyroid, total thyroidectomy

DIAGNOSIS:

1. Lymph Node, Para Tracheal; Excision:
- ONE BENIGN LYMPH NODE (0/1)

2. Lymph Node, Peri Thyroidal; Excision:
- TWO BENIGN LYMPH NODES (0/2)

3. SP: Thyroid, total thyroidectomy:

Tumor Type:

Papillary carcinoma, follicular variant

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 2.0 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

ICD-O-3

Carcinoma, Papillary w/ follicular variant

8340/3

Site: Thyroid, NOS C73.9 ^{for} 11/16/10

[page 2 of 4]
Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

Left thyroid nodule suspicious for follicular neoplasm on FNA.

Specimens Submitted:

- 1: SP: Para tracheal lymph node
- 2: SP: peri thyroidal lymph node
- 3: SP: Thyroid, total thyroidectomy

DIAGNOSIS:

- 1. LYMPH NODE , PARA TRACHEAL; EXCISION:
- ONE BENIGN LYMPH NODE (0/1)

- 2. LYMPH NODE, PERI THYROIDAL; EXCISION:
- TWO BENIGN LYMPH NODES (0/2)

- 3. SP: Thyroid, total thyroidectomy:

Tumor Type:

Papillary carcinoma, follicular variant

Histologic Grade:

Well differentiated

Mitotic Activity:

Not Identified

Tumor Necrosis:

Not Identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 2.0 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not Identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

[page 3 of 4]
Tumor Multicentricity:

Papillary microcarcinoma, 0.6cm (right lobe)

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Parathyroid Glands:

Not identified

Lymph Nodes:

Two benign lymph nodes (0/2)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1.) The specimen is received fresh, labeled "paratracheal lymph node" and consists of a single pink tan firm lymph node(1.2 x 0.5 x 0.4 cm). Bisected and entirely submitted.

Summary of sections:

BLN-- bisected lymph nodes

2.) The specimen is received fresh, labeled "perithyroidal lymph node" and consists of two pink tan firm lymph nodes measuring 0.8 and 0.5 cm in greatest dimension. Entirely submitted.

Summary of sections:

LN -- lymph nodes

3.) The specimen is received fresh, labeled "total thyroid, stitch marks left superior pole" and consists of a thyroid weighing 20.5 grams. The right lobe measures 3.5 x 2.4 x 1.5 cm, the left lobe measures 4.5 x 2.8 x 1.8 cm and the isthmus measures 1.2 x 0.6 x 0.6 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals round tan/yellow, well circumscribed mass(2.0 x 1.4 x 1.2 cm) in the lower pole of the left lobe. Sections through the remaining tissue reveal irregular white firm area in the left upper pole, and 0.6 x 0.6 x 0.5 stellate white fibrous area in the mid right lobe. The remaining thyroid parenchyma is red tan and meaty. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N -- nodule left lobe

RL - right lobe

LL - left lobe

IS - isthmus

Summary of Sections:

Part 1: SP: Para tracheal lymph node

[page 4 of 4]
Block	Sect. Site	PCs
1	BLN	1

Part 2: SP: peri thyroidal lymph node

Block	Sect. Site	PCs
1	LNS	1

Part 3: SP: Thyroid, total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
4	LL	4
5	N	5
6	RL	6

Source: NCI Genomic Data Commons file 29d92259-0c3c-4c1b-8713-b790b1225dca (TCGA-DJ-A13W.00FB68C5-7946-4E69-9019-4E8BF9EB6A94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).